CCDI case PBCBTY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cb6d3298-158b-48b2-9bb6-584ebea6fa8e

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.9 years (1,428 days).

Biospecimens (3 samples)
- Sample 0DNMA3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNMAI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNMAT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
